TCGA case TCGA-DS-A1OB — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/29a48c93-bade-4346-a901-de35a6537337

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 45 years; Vital status: Dead; Days to death: 861 days (2.4 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 45.7 years (16,685 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; AJCC pathologic T: T1b2; AJCC pathologic N: N1; AJCC pathologic M: M0; FIGO stage: Stage IB; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 16; Lymph nodes tested: 31; Lymphatic invasion present: Yes.
   Pathology details: Lymph node involved site: Iliac-common.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 70 days; Days to treatment end: 121 days; Treatment dose: 5,040 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 675 days (1.8 years); Days to treatment end: 710 days (1.9 years); Number of cycles: 6; Treatment dose: 1,008 mg; Prescribed dose: 1.5; Prescribed dose units: AUC.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 675 days (1.8 years); Days to treatment end: 710 days (1.9 years); Number of cycles: 6; Treatment dose: 660 mg; Prescribed dose: 60; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 745 days (2.0 years); Days to treatment end: 765 days (2.1 years); Number of cycles: 4; Treatment dose: 1,500 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 784 days (2.1 years); Days to treatment end: 800 days (2.2 years); Number of cycles: 2; Treatment dose: 400 mg; Prescribed dose: 1.7; Prescribed dose units: AUC.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 784 days (2.1 years); Days to treatment end: 800 days (2.2 years); Number of cycles: 2; Treatment dose: 200 mg; Prescribed dose: 60; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 798 days (2.2 years); Days to treatment end: 814 days (2.2 years); Treatment dose: 2,340 cGy; Course number: 2; Number of fractions: 13; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Number of cycles: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Number of cycles: 3.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 47.5 years (17,337 days); Days to diagnosis: 652 days (1.8 years); Prior treatment: Yes.

Follow-up (3 entries)
- Day 29 (preoperative): ECOG performance status: 1.
- Day 652 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to progression: 652 days (1.8 years).
- Days to follow up: 861 days (2.4 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 152 cm; BMI: 31.2.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 3.

Exposures
- Exposure type: Tobacco.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DS-A1OB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-DS-A1OB-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 30.
- Sample TCGA-DS-A1OB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 1; Pregnant at diagnosis: No; Total pregnancy count: 4; Tumor response: Progression; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Margins involved hysterectomy: Other Location, specify; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion: Present; Corpus involvement: Absent.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator); Pos lymph node location: Common iliac; Pos lymph node location: Para-aortic.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; Radiation adjuvant indicator: Yes; Radiation therapy xrt type: External beam radiation; Chemo concurrent type other: Taxol; Chemo concurrent fractions total: 3; New tumor event type: Distant Metastasis; New tumor event site: Head & Neck; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, Radiation supplemental: Radiation therapy status: Completed as Planned.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3: Regimen number: 2; Therapy regimen: Recurrence.
- Drug treatment 4: Regimen number: 2; Pharmaceutical therapy drug name: Taxol; Therapy regimen: Recurrence.
- Drug treatment 4, Route of administrations: Route of administration: IV.
- Drug treatment 5: Regimen number: 4; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 3; Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 861 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 861 days; disease-free interval: event (new tumor event after initially disease-free), 652 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 652 days.
